HCMI case HCM-CSHL-0618-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8badcb2e-30f1-47ad-91f1-d832d6289f6a

Demographics
Sex at birth: male; Year of birth: 1934; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.2; Tissue or organ of origin: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 84.9 years (31,013 days); AJCC staging edition: 8th; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: M1a; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 295 days.
   Recorded as not given: neoadjuvant treatment (type not reported).
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.7; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 85.8 years (31,334 days); Days to diagnosis: 321 days.

Follow-up (2 entries)
- Days to follow up: 841 days (2.3 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 323.

Molecular and laboratory tests
- MLH1 methylation: Equivocal.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 70 kg; Height: 170 cm; BMI: 24.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0618-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0618-C18-06A-01-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 18; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 6.
  Slide HCM-CSHL-0618-C18-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 19; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 7.
- Sample HCM-CSHL-0618-C18-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0618-C18-11A-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0618-C18-11A-S2-HE: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0618-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
